Somatic mutation profile of tumor specimen TARGET-10-PAPCPB-09A (aliquot TARGET-10-PAPCPB-09A-01D) from TARGET case TARGET-10-PAPCPB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,525 days).
Specimen TARGET-10-PAPCPB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78338d45-ebb2-4c05-9245-f9ae3af4a476.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCPB-14A (Bone Marrow Normal), aliquot TARGET-10-PAPCPB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd6f752-03f2-4989-a733-c5d3e02644ca

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH11X | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967297768, COSV53455530; called by muse, mutect2, varscan2
- APCDD1 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CWC22 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- IZUMO3 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.33); called by muse, mutect2, varscan2
- NSD2 | c.3025G>C p.D1009H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- UBA2 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB13 | c.978C>T p.Y326= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs773194630, COSV54027608; called by muse, mutect2, varscan2
- VSTM1 | c.96C>T p.H32= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs746329632; called by muse, mutect2
